MMRF case MMRF_2253 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/bedbe1b3-f29e-42c2-b80e-c7a1a510af80

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Dead; Days to death: 744 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.4 years (22,422 days); ISS stage: II; Days to last known disease status: 744 days (2.0 years); Days to last follow up: 744 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 157 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 164 days; Days to treatment end: 164 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 165 days; Days to treatment end: 166 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 166 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 495 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 514 days (1.4 years); Days to treatment end: 710 days (1.9 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 514 days (1.4 years); Days to treatment end: 716 days (2.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 716 days (2.0 years); Days to treatment end: 744 days (2.0 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 719 days (2.0 years); Days to treatment end: 744 days (2.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 744.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 1): M Protein 6.57 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 53.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 2.19 g/L; Immunoglobulin A 79.8 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 4.5 µg/mL; Lactate Dehydrogenase 1.65 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.1 mmol/L; Albumin 29 g/L; Total Protein 12.2 g/dL; Glucose 5.83 mmol/L; C-Reactive Protein 0.7 mg/dL.
- Day 64 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.07 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 4.27 g/L; Immunoglobulin A 8.13 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 9.57 mmol/L.
- Day 162 (ECOG 1): M Protein 0.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 6.76 g/L; Immunoglobulin A 10.5 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 266 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 38.4 g/L; Total Protein 6.8 g/dL; Glucose 8.36 mmol/L.
- Day 260 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 5.37 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.1 g/dL; Glucose 9.41 mmol/L.
- Day 331 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.37 mg/dL; Immunoglobulin G 6.07 g/L; Immunoglobulin A 1.04 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 6.49 mmol/L.
- Day 428 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 1.95 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42.9 g/L; Total Protein 6.7 g/dL; Glucose 8.64 mmol/L.
- Day 508 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.49 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 5.04 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.2 mmol/L; Glucose 6.11 mmol/L.
- Day 619 (ECOG 1): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 3.49 g/L; Immunoglobulin A 2.97 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 39.5 g/L; Total Protein 6.4 g/dL; Glucose 8.03 mmol/L.
- Day 716 (ECOG 1): M Protein 2.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.17 mg/dL; Immunoglobulin G 2.34 g/L; Immunoglobulin A 24.5 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 36.5 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.35 mmol/L; Albumin 35.2 g/L; Total Protein 8.4 g/dL; Glucose 8.03 mmol/L.

Other clinical attributes
- Day -16: Weight: 87 kg; Height: 176 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Melanoma; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2253_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_2253_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
